Somatic mutation profile of tumor specimen MMRF_1210_2_BM_CD138pos (aliquot MMRF_1210_2_BM_CD138pos_T1_KHS5U_L16525) from MMRF case MMRF_1210, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.2 years (24,550 days).
Specimen MMRF_1210_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 717f4cb2-7f10-4df4-89b6-e1d3a8b03836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1210_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1210_1_PB_Whole_C1_KHS5U_L16530; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bb12156-75ff-4819-b013-9ac4dfc5ce50

The open-access MAF lists 94 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 25, Intron 16, Silent 8, 5'UTR 5, 5'Flank 3, RNA 3, Splice Region 2, Splice Site 2, 3'Flank 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751405516; called by muse, mutect2
- AFF1 | c.3065C>G p.T1022S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1195725970; called by muse, mutect2, varscan2
- C7orf31 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs1465966597; called by muse, mutect2, varscan2
- CEP162 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57619656; called by muse, mutect2, varscan2
- CRMP1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs910781348, COSV61482769; called by muse, mutect2, varscan2
- FSIP2 | c.17989G>C p.E5997Q | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs773605266, COSV58080005; called by muse, mutect2, varscan2
- IGHV1-69 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs567659422; called by muse, mutect2, varscan2
- KIF26B | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1389384417, COSV69465493; called by muse, mutect2
- LRRC66 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs534526166; called by muse, mutect2, varscan2
- RASA2 | c.2275_2276del p.E759Kfs*12 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs756946687; called by mutect2, pindel, varscan2
- SEMA6A | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs772134310; called by muse, mutect2, varscan2
- SPOCK3 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV62726899; called by muse, mutect2, varscan2
- STAT3 | c.1366-5C>T | Splice Region (SNP) | VAF 25/50 reads (50%) | catalogued as rs951615323; called by muse, mutect2, varscan2
- STYXL2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768021668, COSV54810267; called by muse, mutect2, varscan2
- UBR5 | c.8187+1G>A p.X2729_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55282267; called by muse, mutect2, varscan2
- ZNF257 | c.757A>G p.R253G | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71306613; called by muse, varscan2
- ADGRL2 | c.2338-8T>C | Splice Region (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- CCDC61 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC90B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DNAJB8 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 139/154 reads (90%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4G1 | c.630+1G>A p.X210_splice (on ENST00000346169 / NM_198241.3; = p.X14_splice on NM_004953.5) | Splice Site (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- FAT4 | c.2333T>C p.I778T | Missense Mutation (SNP) | VAF 109/301 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- IGHV2-70D | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IKZF3 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL45 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO9A | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PABPN1 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PATJ | c.647T>A p.I216N | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PDE10A | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAB3A | c.143C>G p.T48R | Missense Mutation (SNP) | VAF 180/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TXNDC5 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB16 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- H3C3 | c.123C>T p.R41= | Silent (SNP) | VAF 74/157 reads (47%) | catalogued as rs372565854; called by muse, mutect2, varscan2
- MLXIPL | c.1020G>C p.V340= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- PHC3 | c.2394G>A p.L798= (on ENST00000494943 / NM_001308116.2; = p.L810= on NM_024947.4) | Silent (SNP) | VAF 96/213 reads (45%) | catalogued as COSV71948442; called by muse, mutect2, varscan2
- PHLPP1 | c.681C>T p.A227= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1308018838; called by muse, mutect2, varscan2
- RNASEH2A | c.726G>A p.Q242= | Silent (SNP) | VAF 32/159 reads (20%) | called by muse, mutect2, varscan2
- SLC19A1 | c.871C>T p.L291= | Silent (SNP) | VAF 148/469 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.15330C>T p.F5110= (on ENST00000591111; = p.F4183= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/223 reads (31%) | called by muse, mutect2, varscan2
- ZNF26 | c.747G>A p.Q249= | Silent (SNP) | VAF 71/159 reads (45%) | called by muse, mutect2, varscan2
- AC012236.1 | n.170C>G | RNA (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- ANKRD26P1 | chr16:46518362 A>T | 5'Flank (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- C3orf18 | c.234+45T>G | Intron (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- C9orf57 | c.*302C>A | 3'UTR (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- CEP350 | c.*1426C>T | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- CHPF2 | c.-686T>C | 5'UTR (SNP) | VAF 44/178 reads (25%) | catalogued as rs190803273; called by muse, mutect2, varscan2
- CICP28 | chr7:56811868 G>A | 3'Flank (SNP) | VAF 8/48 reads (17%) | catalogued as rs1210491597; called by muse, mutect2, varscan2
- COL4A1 | c.553-17T>C | Intron (SNP) | VAF 27/71 reads (38%) | catalogued as rs1439737234; called by muse, varscan2
- DEPP1 | c.*1149C>G | 3'UTR (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- EP400 | c.*387A>G | 3'UTR (SNP) | VAF 17/44 reads (39%) | catalogued as rs1031934661, COSV57784755; called by muse, mutect2, varscan2
- ETS1 | c.*391T>G | 3'UTR (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- FZD8 | c.*1025C>G | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- GPR78 | c.-158G>A | 5'UTR (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- GRHL3 | c.17+32T>C | Intron (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- GRM5 | c.662-61818T>G | Intron (SNP) | VAF 83/241 reads (34%) | called by muse, mutect2, varscan2
- GSTM4 | c.567+338A>C | Intron (SNP) | VAF 74/83 reads (89%) | called by muse, mutect2, varscan2
- GYPA | c.136+116A>C | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99301327; called by muse, mutect2, varscan2
- H4C9 | c.*56C>T | 3'UTR (SNP) | VAF 33/90 reads (37%) | catalogued as COSV62889813; called by muse, mutect2, varscan2
- HS2ST1 | c.*1713del | 3'UTR (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.-34T>A | 5'UTR (SNP) | VAF 34/88 reads (39%) | catalogued as rs567710056; called by muse, varscan2
- IGLL5 | c.-47G>C | 5'UTR (SNP) | VAF 35/72 reads (49%) | catalogued as rs567223608, COSV101597139; called by muse, mutect2, varscan2
- IL17RD | c.*4164G>T | 3'UTR (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- KIF25 | c.93-28A>G | Intron (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.*71C>A | 3'UTR (SNP) | VAF 105/392 reads (27%) | catalogued as rs1228635274; called by muse, mutect2, varscan2
- LMBRD2 | c.*5610A>T | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- MAP2K1 | c.1068+91C>T | Intron (SNP) | VAF 97/210 reads (46%) | called by muse, mutect2, varscan2
- MGA | c.*27G>T | 3'UTR (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- MIR5007 | n.2G>C | RNA (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- MMP27 | c.-11G>T | 5'UTR (SNP) | VAF 97/332 reads (29%) | called by muse, mutect2, varscan2
- NDST1 | c.*3176C>G | 3'UTR (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- NELFA | c.668-137C>A | Intron (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- NPY5R | c.*8C>T | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- OR10AB1P | n.1361T>C | RNA (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- P4HTM | chr3:48990215 C>T | 5'Flank (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- PDCL | c.*1127C>T | 3'UTR (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- PREX2 | c.*3890T>G | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- PRX | c.382-81C>G | Intron (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- QDPR | c.629+476C>G | Intron (SNP) | VAF 40/145 reads (28%) | catalogued as rs1031603658; called by muse, mutect2, varscan2
- RNF185 | c.*2306G>A | 3'UTR (SNP) | VAF 4/22 reads (18%) | catalogued as rs370797100; called by muse, mutect2
- SIPA1L3 | c.2030-63G>A | Intron (SNP) | VAF 49/209 reads (23%) | catalogued as rs764851309; called by muse, mutect2, varscan2
- SNX33 | c.*3636G>A | 3'UTR (SNP) | VAF 62/260 reads (24%) | called by muse, mutect2, varscan2
- SRSF6 | c.*751A>C | 3'UTR (SNP) | VAF 51/84 reads (61%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645388 A>G | 5'Flank (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- TMEM185B | c.*5del | 3'UTR (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- TNS1 | c.4961+83T>A | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- TRMO | c.410-442G>A | Intron (SNP) | VAF 60/222 reads (27%) | catalogued as rs770686239, COSV100796018; called by muse, mutect2, varscan2
- TRPM3 | c.1154+8103T>C | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.2410-28G>A | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- VNN1 | c.*511G>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- Z82198.2 | chr22:33166799 G>C | 3'Flank (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- ZNF341 | c.*205T>C | 3'UTR (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- ZNF516 | c.*3985C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- ZNF525 | c.*621A>G | 3'UTR (SNP) | VAF 76/336 reads (23%) | called by muse, mutect2, varscan2
- ZNF720 | c.*49G>C | 3'UTR (SNP) | VAF 174/421 reads (41%) | called by muse, mutect2
